MMRF case MMRF_1339 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b70aed1f-ffa9-4d0c-8a4c-f75f330a0d16

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 79 years; Vital status: Dead; Days to death: 186 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 79.2 years (28,931 days); ISS stage: III; Days to last known disease status: 186 days; Days to last follow up: 186 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 24 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 186.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -23: M Protein 4.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1484 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.54 mg/dL; Immunoglobulin G 71 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 29.1 µg/mL; Hemoglobin 7.69 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 7.5 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 9.82 mmol/L; Calcium 2.05 mmol/L; Glucose 6.05 mmol/L.
- Day 51: M Protein 4.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1484 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.54 mg/dL; Immunoglobulin G 71 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 29.1 µg/mL; Hemoglobin 5.46 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 6.1 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 171 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Glucose 6.88 mmol/L.
- Day 138: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 31.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Immunoglobulin G 7.41 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.76 g/L; Hemoglobin 6.88 mmol/L; Leukocytes 5.1 ×10⁹/L; Platelets 98 ×10⁹/L; Creatinine 145 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 5.23 mmol/L.

Other clinical attributes
- Day -23: Weight: 78 kg; Height: 177 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.

Biospecimens (2 samples)
- Sample MMRF_1339_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -23 days.
- Sample MMRF_1339_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -23 days.
